CCDI case PBCDSP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/39eb12e5-b8be-42d7-a248-c551639ee72e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.6 years (208 days).

Biospecimens (3 samples)
- Sample 0DPJSB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPJSM, 0DPJT7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
